Somatic mutation profile of tumor specimen TCGA-BR-4294-01A (aliquot TCGA-BR-4294-01A-01D-1126-08) from TCGA case TCGA-BR-4294, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; Tumor grade: G2; Age at diagnosis: 65.0 years (23,758 days).
Specimen TCGA-BR-4294-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8fcfb807-78e8-4679-a47c-575ef36db96a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-4294-11A (Solid Tissue Normal), aliquot TCGA-BR-4294-11A-01D-1126-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7219341e-a337-4748-9a31-43b6b520b284

The open-access MAF lists 33 somatic variants for this specimen: 24 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 7, Frame Shift Ins 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MED12 | c.3670C>T p.L1224F | Missense Mutation (SNP) | VAF 15/17 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057519912, COSV61329632, COSV61332429; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BTBD11 | c.1711G>A p.D571N (on ENST00000280758 / NM_001018072.2; = p.D108N on NM_001017523.2) | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.946); catalogued as COSV55023215; called by muse, mutect2
- BUB1 | c.1084G>T p.V362F | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.218); catalogued as COSV57063138; called by muse, mutect2, varscan2
- CAMTA1 | c.2399G>A p.S800N | Missense Mutation (SNP) | VAF 64/71 reads (90%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV57896963; called by muse, mutect2, varscan2
- CWF19L1 | c.838C>T p.L280F | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV62499175; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.18G>T p.R6S | Missense Mutation (SNP) | VAF 53/438 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.058); catalogued as rs747497403; called by muse, mutect2, varscan2
- ITIH5 | c.2212C>T p.R738C | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs903653130, COSV53663301; called by muse, mutect2, varscan2
- KIAA2026 | c.3778G>A p.A1260T | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs1484072500, COSV67354541; called by muse, mutect2, varscan2
- LRRC46 | c.398G>C p.S133T | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.212); catalogued as COSV51635597; called by muse, mutect2, varscan2
- MED13 | c.95A>T p.K32I | Missense Mutation (SNP) | VAF 47/86 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV67263216; called by muse, mutect2, varscan2
- MUC16 | c.6149C>A p.S2050Y | Missense Mutation (SNP) | VAF 65/162 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV67461989; called by muse, mutect2
- NCAN | c.1993G>A p.A665T | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs747752512, COSV53050243; called by muse, mutect2, varscan2
- NCOA2 | c.1025C>T p.S342F | Missense Mutation (SNP) | VAF 42/44 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV71763874; called by muse, mutect2, varscan2
- PAMR1 | c.329G>C p.G110A | Missense Mutation (SNP) | VAF 71/127 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53511608, COSV53516926; called by muse, mutect2, varscan2
- PHLDA2 | c.228C>A p.D76E | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.754); catalogued as rs1480741227, COSV56539847; called by muse, mutect2, varscan2
- PLXNA2 | c.3924C>G p.D1308E | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV65440087; called by muse, mutect2, varscan2
- RNF213 | c.2555A>C p.H852P | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100172948; called by muse, mutect2, varscan2
- SPRED1 | c.875A>T p.Y292F | Missense Mutation (SNP) | VAF 32/43 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV54435851; called by muse, mutect2, varscan2
- ST3GAL5 | c.437A>G p.H146R (on ENST00000377332; = p.H186R on NM_003896.4) | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.073); catalogued as rs1243393145, COSV60385582; called by muse, mutect2, varscan2
- TAF1L | c.3868G>A p.G1290R | Missense Mutation (SNP) | VAF 65/151 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54261123, COSV54268768; called by muse, mutect2, varscan2
- TMEM126B | c.622G>A p.G208R | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1201796267, COSV62670820; called by muse, mutect2, varscan2
- USP7 | c.1075A>T p.N359Y | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61214268; called by muse, mutect2, varscan2
- ARHGAP17 | c.1694T>G p.L565R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.184); called by muse, varscan2
- SPHKAP | c.550_553dup p.V185Afs*19 | Frame Shift Ins (INS) | VAF 9/56 reads (16%) | called by mutect2, pindel, varscan2
- ADGRB3 | c.3487A>C p.R1163= | Silent (SNP) | VAF 33/51 reads (65%) | catalogued as COSV53241952; called by muse, mutect2, varscan2
- FSIP1 | c.1002C>T p.S334= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV63224511; called by muse, mutect2, varscan2
- FTO | c.1011C>T p.R337= | Silent (SNP) | VAF 37/38 reads (97%) | catalogued as COSV67111382; called by muse, mutect2, varscan2
- PCDHB13 | c.1701C>T p.N567= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs782741589, COSV99506622; called by muse, mutect2, varscan2
- PXDN | c.453A>C p.P151= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs1273526287, COSV99412094; called by muse, mutect2, varscan2
- RNLS | c.273G>A p.S91= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs148977593; called by muse, mutect2, varscan2
- ZBTB39 | c.1014G>A p.R338= | Silent (SNP) | VAF 63/149 reads (42%) | catalogued as rs1425528574, COSV55629089; called by muse, mutect2, varscan2
- AP001425.1 | chr21:38208276 C>A | 5'Flank (SNP) | VAF 72/154 reads (47%) | catalogued as rs769461136; called by muse, mutect2, varscan2
- RFX4 | c.1633+14C>T | Intron (SNP) | VAF 9/109 reads (8%) | called by muse, mutect2
